Surgical pathology report (de-identified scan), TCGA case TCGA-IB-A5SO, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-A5SO-01A (Primary Tumor).

[page 1 of 3]
Note: If you do not see "END OF PRINTED REPORT" at the bottom of the report **YOU DO NOT HAVE THE ENTIRE REPORT**. Please try print.

JOB

CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected

Time Reported

Order Number

Status

Final

Ordering Provider

Relevant
Information
Location

Copied To

Report Patient
Demographics
(for verification
purposes)

Name:

Date of Birth:
Sex: M

ILD-0-3

Adenocarcinoma, ductal NOS
850013

Site: Head of pancreas
C25.0

JW 4/2/13

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number
Collected Date/Time
Received Date/Time
Pathologist

Specimen Description

- A) Omentum
- B) Node of importance
- C) Whipple Specimen
- D) Superior mesenteric artery margin
- E) SMA Margin # 2
- F) Portal vein resection

Clinical Information

Pancreatic Cancer
Infectious patient: No
Immunocompromised: No
History of neoplasm: No

Diagnosis

- A: Omentum, Resection:
- Benign fatty tissue with focal hemorrhage
- B: Lymph Node, (Node of Importance), Excision:
- Two benign, reactive lymph nodes (0/2)
- C: Distal Stomach, Head of Pancreas, Bile Duct, and Proximal Duodenum,
Whipple Resection:
- Moderately differentiated invasive adenocarcinoma involving the

[page 2 of 3]
head of the pancreas and wall of the duodenum (see synoptic report for details)

- D: Soft Tissue, (Superior Mesenteric Artery), Excision:
- Metastatic adenocarcinoma is present in one lymph node (1/1). No extranodal soft tissue extension is seen. Benign fibroadipose tissue is also noted
- E: Soft Tissue, (SMA margin #2), Excision:
- Invasive adenocarcinoma is present in fibroadipose tissue. No vascular involvement is identified. Four benign lymph nodes are present (0/4)
- F: Soft Tissue, (Portal Vein), Excision:
- Invasive adenocarcinoma is present in fibroconnective tissue and within the wall of a large vein. Adenocarcinoma is also present in

one of two lymph nodes (1/2)

Electronically signed by:

Synoptic Report

C: Pancreas (Exocrine), Macroscopic

SPECIMEN:

Head of pancreas

Duodenum

Stomach

Common bile duct

Adjacent large vessels

Portal vein

Other large vessel: superior mesenteric artery

PROCEDURE:

Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy

TUMOR SITE:

Pancreatic head

TUMOR SIZE:

Greatest dimension: 3.8 cm

C: Pancreas (Exocrine), Microscopic

HISTOLOGIC TYPE:

Ductal adenocarcinoma

HISTOLOGIC GRADE:

G2: Moderately differentiated

MICROSCOPIC TUMOR EXTENSION:

Tumor invades duodenal wall

Tumor invades peripancreatic soft tissues

MARGINS:

Margins uninvolved by invasive carcinoma

Distance of invasive carcinoma from closest margin: 1 mm

Specified margin: pancreatic

TREATMENT EFFECT (applicable to carcinomas treated with neoadjuvant therapy):

Not known

LYMPH-VASCULAR INVASION:

Present

PERINEURAL INVASION:

Present

PRIMARY TUMOR (pT):

pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery

REGIONAL LYMPH NODES (pN):

pN1: Regional lymph node metastasis

[page 3 of 3]
Not specified

Gross Description

Gross Description
Received are specimens A to F All requisitions and specimen containers are labelled
with the patient's name, The cassettes and AP identifiers are
labelled with the Surgical Number

A. The specimen is received fresh, labelled "omentum" and consists of an irregular portion of hemorrhagic fatty tissue measuring 35 x 12 x 1 cm. Apart from the hemorrhagic areas, the tissue is unremarkable. Representative sections are submitted in A1 to A3.

B. The specimen is received fresh, labelled "node of importance", and consists of fragments of yellow- red soft tissue which measure together approximately 2.5 x 1.0 x 0.4 cm. Submitted in toto in cassettes B1 and B2.

C. The specimen is received fresh, labelled "Whipple specimen", and consists of a resection of the proximal duodenum, distal stomach, and head of pancreas. The common bile duct is identified via a stent and this is removed to reveal a dilated bile duct measuring up to 1 cm in diameter and 4 cm in length. The ampulla demonstrates a slightly irregular granular area which measures 1.3 cm in diameter. The surrounding gastric and duodenal mucosa are otherwise unremarkable. On sectioning deep to the ampullary region, the pancreatic head is diffusely abnormal and appears replaced by a fibrotic whitish process measuring 3.8 cm. There is no well defined lesion within this although variable areas of fibrosis, hemorrhagic, and microcystic change are noted. No normal pancreas is identified.

- C1- Bile duct resection margin
C2- proximal gastric margin
C3- distal duodenal margin
C4- pancreatic resection margin
C5-C10- pancreas lesion
C11-C15- potential lymph nodes.

D. The specimen is received fresh, labelled "superior mesenteric artery margin", and consists of an irregular portion of fibroadipose tissue measuring 2.3 x 1.6 x 0.5 cm. Submitted in toto in a single cassette D1.

E. The specimen is received fresh labelled "SMA margin # 2", and consists of an irregular portion of yellow-white fibroadipose tissue measuring 3.0 x 2.5 x 1.5 cm. On sectioning, the tissue demonstrates firm white fibrotic tissue. Specimen is bisected and submitted in toto in cassettes E1 and E2.

F. The specimen is received fresh, labelled "portal vein resection", and consists of an irregular portion of fibroadipose soft tissue measuring 4.8 x 2.5 x 1.6 cm. On sectioning, the tissue is firm and fibrous, but no focal lesions are identified and no vessel lumen is seen. Representative sections are submitted in F1 and F2.

Accession
Number
Encounter
Number
Patient Location

- END OF PRINTED REPORT -

Discrepant Discrepancy		✓
Primary Tumors Site Discrepancy		✓
Site Attributions		✓
Primary Malignancy History		✓
Primary synchronous Primary Noted		✓
Primary Site Initials	BTP	

Source: NCI Genomic Data Commons file 12cc1f27-3e19-45a1-8401-089602f8865b (TCGA-IB-A5SO.F2ED454A-150F-4114-A0FA-43B2705AAA02.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).